Somatic mutation profile of tumor specimen TARGET-10-PARCDZ-09A (aliquot TARGET-10-PARCDZ-09A-01D) from TARGET case TARGET-10-PARCDZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,967 days).
Specimen TARGET-10-PARCDZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d29fa030-54c7-4739-a9ee-5d5ed8c08c8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCDZ-10A (Blood Derived Normal), aliquot TARGET-10-PARCDZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb3ffa5e-842c-48bb-9406-cc1ff007032f

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CD | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 39/80 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs397518423, CM067447, COSV63126880; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2
- SALL1 | c.2804C>T p.T935M | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs755926434, COSV51753209, COSV51761394; called by muse, mutect2, varscan2
